Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3678, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3678-01A (Primary Tumor).

Diagnosis:

- 1.: Colon resection material (sigmoid) with tumor-free, oral and aboral resection margins includes an ulcerated, moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria and solitary regional lymph node metastases (G2, pT2 pN1 1/26 L1, V0, R0).
- 2.: Inflammation-free small intestine or Meckel's diverticulum without evidence of tissue heterotopy.

Source: NCI Genomic Data Commons file 0a4a8a04-0bcf-408b-b6b2-a54391ee384b (TCGA-AA-3678.C37DB00C-1AE4-44FB-94C0-6348AEC56948.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).